Somatic mutation profile of tumor specimen TCGA-66-2766-01A (aliquot TCGA-66-2766-01A-01W-0877-08) from TCGA case TCGA-66-2766, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 54.2 years (19,814 days).
Specimen TCGA-66-2766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04bf660f-32dd-4fef-b130-9d2d4dcf6f22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2766-11A (Solid Tissue Normal), aliquot TCGA-66-2766-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa15ef6b-737a-4d93-97fe-44e0c585f9b7

The open-access MAF lists 393 somatic variants for this specimen: 295 protein-altering or splice-affecting, 92 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 255, Silent 92, Nonsense Mutation 18, Splice Site 8, Frame Shift Ins 5, Frame Shift Del 5, Splice Region 3, Intron 3, Translation Start Site 1, RNA 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FH | c.1052C>A p.S351* | Nonsense Mutation (SNP) | VAF 30/140 reads (21%) | catalogued as rs1060500896, COSV63817434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.92G>C p.G31A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67959995, COSV67960100, COSV67961494; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 27/136 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 76/113 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCD2 | c.2032G>T p.D678Y | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58049029, COSV58052297; called by muse, mutect2, varscan2
- ACADS | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM085210, COSV54367929; called by muse, mutect2, varscan2
- ACER1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 32/139 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774677805, COSV56834515; called by muse, mutect2, varscan2
- ACSS3 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54083642; called by muse, mutect2, varscan2
- ACVRL1 | c.104C>A p.T35K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.541); catalogued as COSV66359453; called by muse, mutect2, varscan2
- ADAMTS6 | c.2945G>A p.R982Q | Missense Mutation (SNP) | VAF 163/231 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs780850470, COSV58681461; called by muse, mutect2, varscan2
- ADCY4 | c.2726T>C p.F909S | Missense Mutation (SNP) | VAF 29/36 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60251596; called by muse, mutect2, varscan2
- ADGRL2 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV54649521; called by muse, mutect2, varscan2
- AHCTF1 | c.3970C>G p.Q1324E (on ENST00000366508; = p.Q1298E on NM_015446.5) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.009); catalogued as COSV58245230; called by muse, mutect2, varscan2
- AHNAK | c.7133A>T p.D2378V | Missense Mutation (SNP) | VAF 74/155 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV57202201; called by muse, mutect2, varscan2
- AKAP13 | c.2827T>C p.S943P | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV63447391; called by muse, mutect2, varscan2
- AKAP4 | c.2524G>T p.A842S | Missense Mutation (SNP) | VAF 247/279 reads (89%) | SIFT tolerated (0.26); PolyPhen benign (0.297); catalogued as COSV62073502; called by muse, mutect2, varscan2
- ALDOB | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 78/361 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs752633158, COSV66397201, COSV66398226; called by muse, mutect2, varscan2
- AMFR | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as COSV51919557; called by muse, mutect2, varscan2
- ANKRD11 | c.5391G>T p.R1797S | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV56353546; called by muse, mutect2, varscan2
- ANLN | c.1328A>G p.D443G | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV56073520; called by muse, mutect2, varscan2
- APAF1 | c.945A>T p.K315N (on ENST00000551964 / NM_181861.2; = p.K304N on NM_001160.3) | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.19); PolyPhen benign (0.276); catalogued as COSV59661198; called by muse, mutect2, varscan2
- APPL2 | c.1110A>G p.I370M | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV51587668; called by muse, mutect2, varscan2
- ARHGAP29 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53107575, COSV53116559; called by muse, mutect2, varscan2
- ARHGEF4 | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV58117070; called by muse, mutect2, varscan2
- ARID4A | c.2442G>T p.Q814H | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.862); catalogued as COSV62161726, COSV62162431; called by muse, mutect2, varscan2
- ASB5 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 136/181 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV56668218; called by muse, mutect2, varscan2
- ATP10D | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 91/400 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV56703118; called by muse, mutect2, varscan2
- ATP2B2 | c.685A>T p.I229F | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV59487916; called by muse, mutect2, varscan2
- ATP6V0D1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs200216007, COSV52096523; called by muse, mutect2, varscan2
- B3GALT1 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 80/320 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59907874; called by muse, mutect2, varscan2
- BCLAF1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs148729378; called by muse, mutect2, varscan2
- BHMT | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 38/48 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57153238, COSV99165572; called by muse, mutect2, varscan2
- BRINP3 | c.330C>A p.N110K | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV100818196, COSV66511378; called by muse, mutect2, varscan2
- BRSK1 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV58664360; called by muse, mutect2, varscan2
- C4orf19 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52648807; called by muse, mutect2, varscan2
- CARD18 | c.89T>A p.L30* | Nonsense Mutation (SNP) | VAF 224/285 reads (79%) | catalogued as COSV73233127; called by muse, mutect2, varscan2
- CARM1 | c.1665G>C p.M555I | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV53402590, COSV99450213; called by muse, mutect2, varscan2
- CATSPERB | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 106/144 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56421443; called by muse, mutect2, varscan2
- CATSPERG | c.1667G>A p.W556* | Nonsense Mutation (SNP) | VAF 366/502 reads (73%) | catalogued as COSV53045442; called by muse, mutect2, varscan2
- CCDC102B | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV60133463; called by muse, mutect2, varscan2
- CCDC102B | c.1334C>G p.T445S | Missense Mutation (SNP) | VAF 51/73 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as COSV60133470; called by muse, mutect2, varscan2
- CCSER1 | c.1645G>C p.A549P | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.98); catalogued as COSV61402573, COSV61433484; called by muse, mutect2, varscan2
- CDH23 | c.1562T>A p.L521Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54922902; called by muse, mutect2, varscan2
- CDK8 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 93/136 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67419015; called by muse, mutect2, varscan2
- CDKAL1 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772332509, COSV51179365; called by muse, mutect2, varscan2
- CDKAL1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV51179370; called by muse, mutect2, varscan2
- CEP192 | c.2792G>C p.R931T | Missense Mutation (SNP) | VAF 128/180 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV58059376; called by muse, mutect2, varscan2
- CERS4 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781342642, COSV52164925; called by muse, mutect2, varscan2
- CFAP61 | c.3353G>T p.G1118V | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55617697; called by muse, mutect2, varscan2
- CFL1 | c.452A>T p.E151V | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.653); catalogued as COSV57448841; called by muse, mutect2, varscan2
- CHKA | c.548T>C p.M183T | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1291342588, COSV55838245; called by muse, mutect2, varscan2
- CHST11 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 91/133 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.762); catalogued as COSV57983097, COSV57994169; called by muse, mutect2, varscan2
- CLDN16 | c.274G>T p.G92* | Nonsense Mutation (SNP) | VAF 150/401 reads (37%) | catalogued as COSV53226751; called by muse, mutect2, varscan2
- CLK1 | c.282A>C p.E94D | Missense Mutation (SNP) | VAF 372/713 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV58432150; called by muse, mutect2, varscan2
- CNTN5 | c.1176G>T p.W392C | Missense Mutation (SNP) | VAF 37/48 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54275112; called by muse, mutect2, varscan2
- COL11A1 | c.3539G>T p.G1180V | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62171260; called by muse, mutect2, varscan2
- COL14A1 | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 112/508 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52846248; called by muse, mutect2, varscan2
- CPA4 | c.285+2T>C p.X95_splice | Splice Site (SNP) | VAF 66/125 reads (53%) | catalogued as COSV55982139; called by muse, mutect2, varscan2
- CPAMD8 | c.2951G>T p.R984L (on ENST00000651564; = p.R937L on NM_015692.5) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV71595700; called by muse, mutect2, varscan2
- CR2 | c.842del p.P281Lfs*8 | Frame Shift Del (DEL) | VAF 82/144 reads (57%) | catalogued as rs775000443, COSV65505925; called by mutect2, varscan2
- CRYZ | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV61716771; called by muse, mutect2, varscan2
- CUX1 | c.1520G>C p.R507T (on ENST00000437600 / NM_181500.4; = p.R509T on NM_001913.5) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52921854; called by muse, mutect2, varscan2
- CYP11B1 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.39); catalogued as COSV52824341; called by muse, mutect2, varscan2
- DBH | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs775127844, COSV55039525, COSV55041006; called by muse, mutect2, varscan2
- DCAF4L2 | c.689A>G p.Q230R | Missense Mutation (SNP) | VAF 171/238 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV60476131; called by muse, mutect2, varscan2
- DCDC2B | c.422G>A p.S141N | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV52207218; called by muse, mutect2, varscan2
- DCK | c.779T>G p.L260W | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54377478; called by muse, mutect2, varscan2
- DEFA6 | c.194-2A>G p.X65_splice | Splice Site (SNP) | VAF 28/36 reads (78%) | catalogued as COSV99857856; called by muse, mutect2, varscan2
- DHX8 | c.1431G>C p.M477I | Missense Mutation (SNP) | VAF 113/619 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV52250615; called by muse, mutect2, varscan2
- DLG1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.167); catalogued as COSV58377049; called by muse, mutect2, varscan2
- DNAH11 | c.10241C>T p.T3414M | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs779964310, COSV60937035; called by muse, mutect2, varscan2
- DNAH3 | c.7020A>G p.I2340M | Missense Mutation (SNP) | VAF 252/298 reads (85%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV54500751; called by muse, mutect2, varscan2
- DNAJC14 | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 110/521 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV57911973; called by muse, mutect2, varscan2
- DNAJC21 | c.976G>C p.E326Q | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV57758911; called by muse, mutect2, varscan2
- DSCAML1 | c.3001T>A p.S1001T (on ENST00000321322; = p.S941T on NM_020693.4) | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV58380146, COSV58383137; called by muse, mutect2, varscan2
- DTX3L | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 74/135 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs748994219, COSV56143082, COSV99949896; called by muse, mutect2, varscan2
- EFNB2 | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 148/171 reads (87%) | SIFT tolerated (0.2); PolyPhen benign (0.145); catalogued as COSV55362992, COSV55367456; called by muse, mutect2, varscan2
- EIF3F | c.745+1G>T p.X249_splice | Splice Site (SNP) | VAF 38/87 reads (44%) | catalogued as rs113494623, COSV59141135; called by muse, mutect2, varscan2
- EMSY | c.2684G>C p.G895A | Missense Mutation (SNP) | VAF 285/1201 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.034); catalogued as COSV58256905, COSV58257441; called by muse, mutect2, varscan2
- EPHA6 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 466/690 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs760704852, COSV67556568; called by muse, mutect2, varscan2
- EPRS1 | c.3716G>C p.G1239A | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65096936; called by muse, mutect2, varscan2
- ERICH3 | c.743A>G p.N248S | Missense Mutation (SNP) | VAF 108/271 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV58598217; called by muse, mutect2, varscan2
- FAM114A1 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 77/142 reads (54%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV62671697, COSV62673644; called by muse, mutect2, varscan2
- FAM135B | c.1835T>A p.L612H | Missense Mutation (SNP) | VAF 362/538 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV52701917; called by muse, mutect2, varscan2
- FANCM | c.1184-1G>T p.X395_splice | Splice Site (SNP) | VAF 10/14 reads (71%) | catalogued as COSV57496720; called by muse, mutect2
- FARS2 | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 98/320 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51164278; called by muse, mutect2, varscan2
- FASTKD3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.122); catalogued as COSV52941290; called by muse, mutect2, varscan2
- FCRL2 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.065); catalogued as COSV63832384; called by muse, mutect2, varscan2
- FIGNL1 | c.541C>A p.R181S | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1054523452, COSV63553137, COSV63553932; called by muse, mutect2, varscan2
- FKTN | c.1369G>A p.V457I | Missense Mutation (SNP) | VAF 233/293 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs775183646, COSV56307835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT3 | c.2817G>T p.L939F | Missense Mutation (SNP) | VAF 135/177 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54042182; called by muse, mutect2, varscan2
- FREM2 | c.1100A>G p.Q367R | Missense Mutation (SNP) | VAF 71/94 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV54826678; called by muse, mutect2, varscan2
- FSIP2 | c.20710C>A p.Q6904K | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV58077210; called by muse, mutect2, varscan2
- FTO | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.211); catalogued as COSV67109768; called by muse, mutect2, varscan2
- GAP43 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 57/68 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745746040, COSV59342107, COSV59344036; called by muse, mutect2, varscan2
- GJA9 | c.1030C>G p.Q344E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as COSV62531655; called by muse, mutect2, varscan2
- GNE | c.1490G>A p.R497K (on ENST00000396594 / NM_001128227.3; = p.R466K on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/58 reads (79%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.647); catalogued as rs1421444537, COSV64951175; called by muse, mutect2, varscan2
- GPA33 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 126/228 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV54801523; called by muse, mutect2, varscan2
- GPC2 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV52783645, COSV52786686, COSV99445165; called by muse, mutect2, varscan2
- GPR45 | c.849C>A p.H283Q | Missense Mutation (SNP) | VAF 185/559 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as COSV51522561; called by muse, mutect2, varscan2
- GPR83 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV54717216; called by muse, mutect2, varscan2
- GRIA3 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52047488, COSV52078860; called by muse, mutect2
- GRM5 | c.336C>G p.F112L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV59587957, COSV59605851; called by muse, mutect2, varscan2
- GRM8 | c.2174A>G p.Y725C | Missense Mutation (SNP) | VAF 49/109 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1185685926, COSV58797854; called by muse, mutect2, varscan2
- H2BC18 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 116/242 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.716); catalogued as rs782535906, COSV58943636; called by muse, varscan2
- H3C13 | c.273G>T p.M91I | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as COSV100516067; called by muse, mutect2, varscan2
- H4C5 | c.278G>C p.R93T | Missense Mutation (SNP) | VAF 141/355 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV63486069; called by muse, mutect2, varscan2
- HENMT1 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141386408; called by muse, mutect2, varscan2
- HIPK1 | c.2044A>G p.I682V | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV61245455; called by muse, mutect2, varscan2
- HIPK2 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 96/219 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.321); catalogued as rs1357622639, COSV61225147; called by muse, mutect2, varscan2
- HK1 | c.1918G>T p.A640S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV53852506; called by muse, mutect2
- IGFLR1 | c.407A>G p.Q136R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as rs1323039921, COSV53073399; called by muse, mutect2, varscan2
- IGKV3-7 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 49/213 reads (23%) | catalogued as rs545887714; called by muse, mutect2, varscan2
- IGLL1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs758781859, COSV50769746; called by muse, mutect2, varscan2
- IGSF11 | c.746C>A p.T249N (on ENST00000393775 / NM_001015887.3; = p.T248N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 412/506 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV61164780; called by muse, mutect2, varscan2
- IL17RA | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV60051044; called by muse, mutect2, varscan2
- INTS5 | c.2297C>A p.S766* | Nonsense Mutation (SNP) | VAF 20/67 reads (30%) | catalogued as COSV57950103; called by muse, mutect2, varscan2
- ITGA8 | c.3032C>A p.P1011Q | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65223889; called by muse, mutect2, varscan2
- KCNJ9 | c.314A>G p.N105S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV63631397; called by muse, mutect2, varscan2
- KCNK10 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs765748005, COSV56638700; called by muse, mutect2
- KCNK10 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 271/318 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as rs1368825715, COSV56638726; called by muse, mutect2, varscan2
- KCNK10 | c.820C>G p.L274V | Missense Mutation (SNP) | VAF 77/93 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56638745; called by muse, mutect2, varscan2
- KCNK4 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60453431; called by muse, mutect2, varscan2
- KCNN3 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV55211814; called by muse, mutect2, varscan2
- KCNQ5 | c.1933C>A p.Q645K | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV59647670; called by muse, mutect2, varscan2
- KIAA1958 | c.1769A>G p.Q590R | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as rs143861651; called by muse, mutect2, varscan2
- KIF21B | c.3049G>T p.D1017Y | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59751661; called by muse, mutect2, varscan2
- KIF5B | c.2184A>T p.K728N | Missense Mutation (SNP) | VAF 52/94 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV56650387; called by muse, mutect2, varscan2
- KLB | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57299807; called by muse, mutect2, varscan2
- KLHL1 | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 141/183 reads (77%) | catalogued as rs1430588733, COSV64765927, COSV64770873; called by muse, mutect2, varscan2
- KRT20 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 201/440 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.111); catalogued as COSV51423797; called by muse, mutect2, varscan2
- LCE1B | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs1292432640, COSV63980019; called by muse, mutect2, varscan2
- LCE1B | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 87/158 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as COSV63980022; called by muse, mutect2, varscan2
- LCE2C | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.974); catalogued as COSV64228206; called by muse, mutect2, varscan2
- LCE3A | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV59550292; called by muse, mutect2, varscan2
- LDOC1 | c.60C>A p.S20R | Missense Mutation (SNP) | VAF 33/37 reads (89%) | SIFT tolerated (0.57); PolyPhen benign (0.144); catalogued as COSV65159065; called by muse, mutect2, varscan2
- LDOC1 | c.59G>A p.S20N | Missense Mutation (SNP) | VAF 32/36 reads (89%) | SIFT tolerated (0.38); PolyPhen benign (0.068); catalogued as COSV65159069; called by muse, mutect2, varscan2
- LMBR1 | c.1388-1G>T p.X463_splice | Splice Site (SNP) | VAF 108/255 reads (42%) | catalogued as COSV100626618; called by muse, mutect2, varscan2
- LRP1B | c.8506G>A p.E2836K | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67181917; called by muse, mutect2, varscan2
- LRP1B | c.4238G>C p.G1413A | Missense Mutation (SNP) | VAF 102/192 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV67181921; called by muse, mutect2, varscan2
- LRP2 | c.5927C>A p.T1976N | Missense Mutation (SNP) | VAF 154/435 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV55538784; called by muse, mutect2, varscan2
- LTBP4 | c.3286G>A p.E1096K (on ENST00000308370 / NM_001042544.1; = p.E1059K on NM_003573.2) | Missense Mutation (SNP) | VAF 170/802 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52575215; called by muse, mutect2, varscan2
- MARCHF7 | c.1412G>A p.R471K | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV52027190; called by muse, mutect2, varscan2
- MCHR2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 162/321 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs772514447, COSV55999048; called by muse, mutect2, varscan2
- MDN1 | c.4915C>G p.L1639V | Missense Mutation (SNP) | VAF 123/428 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV65516310; called by muse, mutect2, varscan2
- MGAT4C | c.1017T>A p.D339E | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV59829286; called by muse, mutect2, varscan2
- MROH2B | c.3202C>T p.Q1068* | Nonsense Mutation (SNP) | VAF 34/337 reads (10%) | catalogued as COSV68180626; called by muse, mutect2, varscan2
- MROH2B | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 410/678 reads (60%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.998); catalogued as COSV68180631; called by muse, mutect2, varscan2
- MROH7 | c.1999G>T p.G667W | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59867389; called by muse, mutect2, varscan2
- MSR1 | c.401A>T p.N134I | Missense Mutation (SNP) | VAF 292/399 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV50506633; called by muse, mutect2, varscan2
- MTIF3 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.915); catalogued as COSV66949427; called by muse, mutect2, varscan2
- MUC16 | c.3961C>G p.P1321A | Missense Mutation (SNP) | VAF 218/641 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV67440791; called by muse, mutect2, varscan2
- MUC5B | c.4988C>G p.T1663R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV71589671; called by muse, mutect2, varscan2
- MUC5B | c.6827C>G p.T2276S | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.112); catalogued as COSV71589672; called by muse, mutect2, varscan2
- MUC7 | c.59G>T p.S20I | Missense Mutation (SNP) | VAF 152/526 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59216873; called by muse, mutect2, varscan2
- MYH4 | c.5687A>G p.N1896S | Missense Mutation (SNP) | VAF 138/204 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV55111222; called by muse, mutect2, varscan2
- MYO9A | c.3316C>A p.Q1106K | Missense Mutation (SNP) | VAF 71/86 reads (83%) | SIFT tolerated (0.69); PolyPhen benign (0.02); catalogued as COSV61846983; called by muse, mutect2, varscan2
- MYRF | c.2693C>T p.P898L (on ENST00000278836 / NM_001127392.3; = p.P863L on NM_013279.4) | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs1344416402, COSV53885354; called by muse, mutect2, varscan2
- NCAN | c.3355C>A p.R1119S | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs777170009, COSV53046225, COSV99386370; called by muse, mutect2, varscan2
- NCKAP1 | c.2017A>G p.T673A | Missense Mutation (SNP) | VAF 107/253 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV62939483; called by muse, mutect2, varscan2
- NCOA2 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs748237390, COSV71763312; called by muse, mutect2, varscan2
- NFE2L1 | c.485dup p.V163Sfs*14 | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | catalogued as rs773403681; called by mutect2, varscan2
- NID2 | c.2401G>T p.D801Y | Missense Mutation (SNP) | VAF 298/414 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53492374; called by muse, mutect2, varscan2
- NID2 | c.2400G>T p.V800= | Splice Region (SNP) | VAF 296/408 reads (73%) | catalogued as COSV53492384, COSV53502141; called by muse, mutect2, varscan2
- NIN | c.944A>C p.Q315P | Missense Mutation (SNP) | VAF 127/161 reads (79%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV55379109; called by muse, mutect2, varscan2
- NRG2 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as COSV56828579; called by muse, mutect2, varscan2
- NUP42 | c.170T>G p.V57G | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51728599; called by muse, mutect2, varscan2
- OPA1 | c.587C>T p.A196V (on ENST00000361510 / NM_130837.3; = p.A160V on NM_130832.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV100655239; called by muse, mutect2, varscan2
- OR1S1 | c.64A>G p.I22V | Missense Mutation (SNP) | VAF 98/185 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775083801, COSV58705879; called by muse, mutect2, varscan2
- OR2F2 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 165/414 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371979913; called by muse, mutect2, varscan2
- OR4A15 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 248/432 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59033435, COSV59036307; called by muse, mutect2, varscan2
- OR51B2 | c.923A>G p.H308R | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1359874835, COSV60915820; called by muse, mutect2
- OR52B2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 208/436 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as rs746886817, COSV73209176; called by muse, mutect2, varscan2
- OR52E8 | c.941A>T p.K314M | Missense Mutation (SNP) | VAF 149/349 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV66204312; called by muse, mutect2, varscan2
- OR5A1 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 97/492 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV57375567; called by muse, mutect2
- OR5R1 | c.809C>A p.T270K | Missense Mutation (SNP) | VAF 206/372 reads (55%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as rs761333374, COSV56571362; called by muse, mutect2, varscan2
- OR6K3 | c.814C>A p.L272I (on ENST00000368146; = p.L256I on NM_001005327.2) | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.344); catalogued as COSV63745198, COSV63745666; called by muse, mutect2, varscan2
- P2RY13 | c.104G>C p.R35P | Missense Mutation (SNP) | VAF 165/1339 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV56366958; called by muse, mutect2, varscan2
- PACRGL | c.109C>T p.Q37* | Nonsense Mutation (SNP) | VAF 73/230 reads (32%) | catalogued as COSV54841192; called by muse, mutect2, varscan2
- PCDH17 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64971326; called by muse, mutect2, varscan2
- PCDHB6 | c.378T>A p.N126K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50689475; called by muse, mutect2, varscan2
- PCDHGA12 | c.954A>T p.E318D | Missense Mutation (SNP) | VAF 188/233 reads (81%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.044); catalogued as COSV52741829; called by muse, mutect2, varscan2
- PEPD | c.1347C>T p.V449= | Splice Region (SNP) | VAF 9/133 reads (7%) | catalogued as COSV52287017; called by muse, mutect2
- PHF21B | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.748); catalogued as rs760468264, COSV57555193; called by muse, mutect2, varscan2
- PKHD1 | c.3803C>A p.A1268D | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV61858360; called by muse, mutect2, varscan2
- PKHD1L1 | c.7472G>C p.R2491T | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV65736033, COSV65743771; called by muse, mutect2, varscan2
- PKP2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs775318947, COSV50725802; called by muse, mutect2, varscan2
- PLCL2 | c.427A>G p.M143V (on ENST00000615277 / NM_001144382.2; = p.M17V on NM_015184.5) | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV67620363; called by muse, mutect2, varscan2
- PODXL2 | c.884G>T p.G295V | Missense Mutation (SNP) | VAF 49/59 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV61064407; called by muse, mutect2, varscan2
- POLQ | c.6698C>T p.S2233L | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV51744948; called by muse, mutect2, varscan2
- POLQ | c.2140G>T p.A714S | Missense Mutation (SNP) | VAF 273/360 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV51744957; called by muse, mutect2, varscan2
- POLQ | c.2139G>A p.M713I | Missense Mutation (SNP) | VAF 279/366 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV51744971; called by muse, mutect2, varscan2
- POLR3A | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV64930071; called by muse, mutect2, varscan2
- PPARGC1A | c.1099G>T p.G367* | Nonsense Mutation (SNP) | VAF 133/176 reads (76%) | catalogued as COSV53523769; called by muse, mutect2, varscan2
- PRAME | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as COSV67160838; called by muse, mutect2, varscan2
- PRIMPOL | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV59247711; called by muse, mutect2, varscan2
- PRKG2 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 89/321 reads (28%) | catalogued as COSV52318386; called by muse, mutect2, varscan2
- PRUNE2 | c.2116A>C p.K706Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as COSV65037498; called by muse, mutect2, varscan2
- PSD3 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 165/241 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV58960989; called by muse, mutect2, varscan2
- PTCHD4 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59776225; called by muse, mutect2, varscan2
- RASGRF2 | c.1166C>A p.P389H | Missense Mutation (SNP) | VAF 188/271 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54122089; called by muse, mutect2, varscan2
- RASSF9 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV63432353; called by muse, mutect2, varscan2
- REG1A | c.277A>C p.T93P | Missense Mutation (SNP) | VAF 70/274 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV52068123, COSV99286992; called by muse, varscan2
- RERGL | c.26A>G p.Y9C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1156588983, COSV57460694; called by muse, mutect2, varscan2
- RET | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.014); catalogued as rs1313331250, CM1110094, COSV60685932; called by muse, mutect2, varscan2
- RGL4 | c.44G>T p.S15I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); catalogued as COSV51943015; called by muse, mutect2, varscan2
- RHOT1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61713376; called by muse, mutect2, varscan2
- RPL10L | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751834362, COSV53558471; called by muse, mutect2, varscan2
- RYR2 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as COSV63657324; called by muse, mutect2, varscan2
- SARDH | c.1384G>C p.E462Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64098300; called by muse, mutect2, varscan2
- SCEL | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 119/209 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62992714; called by muse, mutect2, varscan2
- SCIN | c.2083A>T p.K695* (on ENST00000297029 / NM_001112706.3; = p.K448* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 75/196 reads (38%) | catalogued as COSV51688774; called by muse, mutect2, varscan2
- SCN10A | c.4960C>G p.L1654V | Missense Mutation (SNP) | VAF 490/644 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71860064; called by muse, mutect2, varscan2
- SCN1A | c.5977A>G p.I1993V (on ENST00000303395 / NM_001202435.3; = p.I1982V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs751750112, COSV57658490; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN1A | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as CM147001, COSV57658506, COSV57664296; called by muse, mutect2, varscan2
- SCN5A | c.1334A>C p.H445P | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV61114779; called by muse, mutect2, varscan2
- SERTAD3 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.829); catalogued as COSV100475030, COSV59324462; called by muse, mutect2, varscan2
- SH3GL2 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 65/91 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66047226; called by muse, mutect2, varscan2
- SHANK2 | c.5500G>C p.G1834R | Missense Mutation (SNP) | VAF 119/212 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53583660; called by muse, mutect2, varscan2
- SLC24A2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 47/66 reads (71%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV53856326, COSV53866161; called by muse, mutect2, varscan2
- SLC32A1 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.254); catalogued as rs778809530, COSV54145482; called by muse, mutect2, varscan2
- SLC37A3 | c.1414A>G p.I472V (on ENST00000326232 / NM_001363375.1; = p.Y371C on NM_032295.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 120/334 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV58262433; called by muse, mutect2, varscan2
- SLC44A5 | c.1433C>T p.A478V | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.028); catalogued as COSV63757797; called by muse, mutect2, varscan2
- SLC5A5 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 139/370 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV55831295; called by muse, mutect2, varscan2
- SLC8A1 | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 117/183 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60469565; called by muse, mutect2, varscan2
- SNAP47 | c.1109C>G p.S370* | Nonsense Mutation (SNP) | VAF 29/160 reads (18%) | catalogued as COSV59916704; called by muse, mutect2, varscan2
- SNTG1 | c.363+1G>T p.X121_splice | Splice Site (SNP) | VAF 16/21 reads (76%) | catalogued as COSV52422826; called by muse, mutect2, varscan2
- SOST | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV57012074; called by muse, mutect2, varscan2
- SOX5 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV58616347; called by muse, mutect2, varscan2
- SPATA17 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 180/360 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV65119075; called by muse, mutect2
- SPEN | c.10606C>G p.R3536G | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV65267809; called by muse, mutect2, varscan2
- SPHKAP | c.1343C>A p.P448H | Missense Mutation (SNP) | VAF 79/103 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60867278; called by muse, mutect2, varscan2
- SPTBN4 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58942911; called by muse, mutect2, varscan2
- SPX | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 155/297 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as rs750496888, COSV57020031; called by muse, mutect2, varscan2
- SWT1 | c.2478G>C p.E826D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.943); catalogued as COSV62252620; called by muse, mutect2, varscan2
- SYNGR1 | c.162G>T p.E54D | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.326); catalogued as rs745901428, COSV99335539; called by muse, mutect2, varscan2
- SYNGR1 | c.163G>T p.G55W | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.716); catalogued as COSV99335544; called by muse, mutect2, varscan2
- SYT5 | c.930C>G p.F310L | Missense Mutation (SNP) | VAF 95/286 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV62829572, COSV62830112; called by muse, mutect2, varscan2
- SYT6 | c.955T>A p.F319I (on ENST00000610222 / NM_001366225.1; = p.F234I on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65772231; called by muse, mutect2, varscan2
- TAFA2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV69171332; called by muse, mutect2, varscan2
- TANC2 | c.3807C>A p.Y1269* | Nonsense Mutation (SNP) | VAF 47/111 reads (42%) | catalogued as COSV67329279; called by muse, mutect2, varscan2
- TBC1D1 | c.2774A>T p.Q925L | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54713316; called by muse, mutect2, varscan2
- TBC1D23 | c.1442G>C p.R481T | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV61366465; called by muse, mutect2, varscan2
- TDRD6 | c.1903G>C p.D635H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as COSV60173645; called by muse, mutect2, varscan2
- TENM4 | c.7712A>C p.K2571T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV53604195; called by muse, mutect2, varscan2
- TLN1 | c.6988G>C p.A2330P | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV59203528; called by muse, mutect2, varscan2
- TMEM132E | c.1556C>A p.T519N (on ENST00000321639; = p.T609N on NM_001304438.2) | Missense Mutation (SNP) | VAF 106/215 reads (49%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.997); catalogued as COSV58694315, COSV58695588; called by muse, varscan2
- TOX3 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 141/561 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV54862368; called by muse, mutect2, varscan2
- TPTE | c.1623G>A p.M541I (on ENST00000618007 / NM_199261.4; = p.M523I on NM_199259.4) | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs758305832; called by muse, mutect2, varscan2
- TRHDE | c.680C>G p.A227G | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV53830330, COSV99669845; called by muse, mutect2, varscan2
- TRPC4 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 129/164 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV58988887, COSV59000757; called by muse, mutect2, varscan2
- TTC13 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 114/465 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as COSV64167619; called by muse, mutect2, varscan2
- TTC17 | c.1938G>C p.L646F | Missense Mutation (SNP) | VAF 38/264 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV50005641; called by muse, mutect2, varscan2
- TTN | c.27542G>C p.R9181T (on ENST00000591111; = p.R8254T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/111 reads (12%) | PolyPhen benign (0.022); catalogued as COSV59861681; called by muse, mutect2, varscan2
- TTN | c.19681G>C p.E6561Q (on ENST00000591111; = p.E5634Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/73 reads (55%) | PolyPhen possibly damaging (0.652); catalogued as rs755499713, COSV59861693; called by muse, mutect2, varscan2
- TYROBP | c.95-1G>A p.X32_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV52887119; called by muse, mutect2, varscan2
- UBE2E3 | c.69C>A p.D23E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV66583695; called by muse, mutect2, varscan2
- UBXN4 | c.1229A>C p.D410A | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV55633102; called by muse, mutect2, varscan2
- UNC5D | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 74/102 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54765579; called by muse, mutect2, varscan2
- URGCP | c.1538A>T p.Q513L (on ENST00000453200 / NM_001077663.3; = p.Q504L on NM_017920.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV56244655; called by muse, mutect2, varscan2
- USP36 | c.827G>T p.R276L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100361473, COSV61749985; called by muse, mutect2, varscan2
- XPO5 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 193/403 reads (48%) | SIFT tolerated (0.89); PolyPhen benign (0.038); catalogued as COSV54827101; called by muse, mutect2, varscan2
- ZBTB3 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67360784, COSV67361584; called by muse, mutect2, varscan2
- ZBTB6 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV65409197, COSV65410847; called by muse, mutect2, varscan2
- ZDHHC17 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58349983; called by muse, mutect2, varscan2
- ZDHHC17 | c.1406G>T p.W469L | Missense Mutation (SNP) | VAF 258/332 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV58349990; called by muse, mutect2, varscan2
- ZFP36L2 | c.54A>T p.T18= | Splice Region (SNP) | VAF 21/30 reads (70%) | catalogued as COSV56696858; called by muse, mutect2, varscan2
- ZIC1 | c.591C>G p.Y197* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV51550200, COSV99292073; called by muse, mutect2, varscan2
- ZNF208 | c.2326C>A p.P776T | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV68099457; called by muse, mutect2, varscan2
- ZNF274 | c.1149G>C p.L383F (on ENST00000610905; = p.L278F on NM_016324.3) | Missense Mutation (SNP) | VAF 63/74 reads (85%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV58762705; called by muse, mutect2, varscan2
- ZNF433 | c.1392C>G p.F464L | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV61398230; called by muse, mutect2, varscan2
- ZNF438 | c.2479G>A p.E827K | Missense Mutation (SNP) | VAF 112/593 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1173884587, COSV59191788, COSV59194159; called by muse, mutect2, varscan2
- ZNF44 | c.349G>A p.E117K (on ENST00000356109 / NM_001164276.2; = p.E69K on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/276 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV61134568; called by muse, mutect2, varscan2
- ZNF445 | c.326G>C p.G109A | Missense Mutation (SNP) | VAF 61/80 reads (76%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV68538335; called by muse, mutect2, varscan2
- ZNF626 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.344); catalogued as COSV74128837; called by muse, mutect2, varscan2
- ZNF626 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 46/412 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as COSV74128839; called by muse, varscan2
- ZNF626 | c.999A>T p.R333S | Missense Mutation (SNP) | VAF 62/388 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.575); catalogued as COSV74128842; called by muse, mutect2, varscan2
- ZNF763 | c.848C>T p.P283L (on ENST00000358987 / NM_001367172.2; = p.P286L on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV59686989; called by muse, mutect2, varscan2
- ZNF80 | c.635C>T p.T212I | Missense Mutation (SNP) | VAF 214/258 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1022493294, COSV57359675; called by muse, mutect2, varscan2
- ZNF804B | c.3601C>T p.H1201Y | Missense Mutation (SNP) | VAF 110/562 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV60814498; called by muse, varscan2
- ZNF804B | c.3757C>G p.P1253A | Missense Mutation (SNP) | VAF 56/434 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV60814506; called by muse, varscan2
- BAHD1 | c.799G>T p.G267W | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by mutect2, varscan2
- CLASP1 | c.3573del p.K1191Nfs*10 | Frame Shift Del (DEL) | VAF 10/23 reads (43%) | called by mutect2, pindel, varscan2
- DIAPH3 | c.3241dup p.R1081Kfs*25 (on ENST00000400324 / NM_001042517.2; = p.R818Kfs*25 on NM_030932.3) | Frame Shift Ins (INS) | VAF 76/190 reads (40%) | called by mutect2, pindel, varscan2
- GLP2R | c.75del p.M26Wfs*59 | Frame Shift Del (DEL) | VAF 13/18 reads (72%) | called by mutect2, pindel, varscan2
- HEATR9 | c.1025T>C p.V342A | Missense Mutation (SNP) | VAF 398/762 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGKV1-9 | c.233G>T p.S78I | Missense Mutation (SNP) | VAF 176/295 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- IL2RB | c.378del p.F127Lfs*6 | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.977C>A p.P326H | Missense Mutation (SNP) | VAF 1445/2032 reads (71%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POSTN | c.2454dup p.A819Sfs*9 | Frame Shift Ins (INS) | VAF 91/150 reads (61%) | called by mutect2, pindel, varscan2
- SHBG | c.522dup p.L175Afs*39 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- SLC7A14 | c.2001del p.I668Ffs*93 | Frame Shift Del (DEL) | VAF 18/165 reads (11%) | called by mutect2, pindel, varscan2
- SYNRG | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- TRIM68 | c.427-15_430del p.X143_splice | Splice Site (DEL) | VAF 46/128 reads (36%) | called by mutect2, pindel
- VAV3 | c.2035dup p.R679Kfs*10 | Frame Shift Ins (INS) | VAF 37/123 reads (30%) | called by mutect2, pindel, varscan2
- ABCA10 | c.1149A>G p.P383= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV52217488; called by muse, mutect2, varscan2
- ACSM2A | c.351T>A p.P117= (on ENST00000219054; = p.P38= on NM_001308169.2) | Silent (SNP) | VAF 94/142 reads (66%) | catalogued as COSV54581657; called by muse, varscan2
- ADAMTS4 | c.618A>G p.R206= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as COSV63487160; called by muse, mutect2, varscan2
- ADGRE3 | c.1728C>A p.A576= | Silent (SNP) | VAF 165/266 reads (62%) | catalogued as COSV53728023; called by muse, mutect2, varscan2
- AFF3 | c.297G>T p.G99= | Silent (SNP) | VAF 56/135 reads (41%) | catalogued as COSV57838347; called by muse, mutect2, varscan2
- AOC3 | c.1203G>T p.G401= | Silent (SNP) | VAF 82/190 reads (43%) | catalogued as COSV53823893; called by muse, mutect2, varscan2
- APBA2 | c.1263G>T p.G421= | Silent (SNP) | VAF 38/44 reads (86%) | catalogued as rs367808207, COSV67104095; called by muse, mutect2, varscan2
- ARHGAP1 | c.60G>C p.L20= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV61237462; called by mutect2, varscan2
- BRAP | c.1626A>T p.T542= | Silent (SNP) | VAF 101/136 reads (74%) | catalogued as COSV59535243; called by muse, mutect2, varscan2
- CCDC85A | c.936G>T p.G312= | Silent (SNP) | VAF 43/318 reads (14%) | catalogued as COSV68147129; called by muse, mutect2, varscan2
- CCHCR1 | c.1557G>A p.L519= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as COSV66182523; called by muse, mutect2, varscan2
- CD248 | c.1875C>T p.S625= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs770987585, COSV60935641; called by muse, mutect2, varscan2
- CFP | c.879C>A p.G293= | Silent (SNP) | VAF 73/84 reads (87%) | catalogued as COSV55949557; called by muse, mutect2, varscan2
- CIB3 | c.195G>C p.L65= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as COSV54165330; called by muse, mutect2, varscan2
- COL12A1 | c.1218C>T p.A406= | Silent (SNP) | VAF 189/693 reads (27%) | catalogued as COSV59388424; called by muse, mutect2, varscan2
- CRLF3 | c.207C>G p.L69= | Silent (SNP) | VAF 144/252 reads (57%) | catalogued as COSV60835135; called by muse, mutect2, varscan2
- CSMD1 | c.2322A>G p.G774= (on ENST00000520002; = p.G773= on NM_033225.6) | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs745825421, COSV59276524; called by muse, mutect2, varscan2
- DLG5 | c.2304A>T p.A768= | Silent (SNP) | VAF 21/95 reads (22%) | catalogued as COSV64946491; called by muse, mutect2
- EDEM1 | c.750C>T p.D250= | Silent (SNP) | VAF 136/388 reads (35%) | catalogued as COSV56580699; called by muse, mutect2, varscan2
- ELF3 | c.99C>T p.A33= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as COSV62836968; called by muse, mutect2, varscan2
- EPB41L3 | c.3162T>G p.A1054= | Silent (SNP) | VAF 79/105 reads (75%) | catalogued as COSV59442680; called by muse, mutect2, varscan2
- FPR3 | c.117C>T p.F39= | Silent (SNP) | VAF 391/546 reads (72%) | catalogued as rs369595664; called by muse, mutect2, varscan2
- FRY | c.6594G>A p.T2198= | Silent (SNP) | VAF 70/139 reads (50%) | catalogued as rs752351313, COSV66564346; called by muse, mutect2, varscan2
- GABRD | c.297G>A p.R99= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as COSV66079766; called by muse, mutect2, varscan2
- GCLM | c.600G>A p.L200= | Silent (SNP) | VAF 57/181 reads (31%) | catalogued as COSV64686689, COSV64687292; called by muse, mutect2, varscan2
- GEN1 | c.756G>T p.L252= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV58055055; called by muse, mutect2, varscan2
- GNGT1 | c.12C>T p.I4= | Silent (SNP) | VAF 56/344 reads (16%) | catalogued as COSV50352293; called by muse, mutect2, varscan2
- GPR6 | c.774G>A p.Q258= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV51570845; called by muse, mutect2, varscan2
- GRM8 | c.2424A>T p.A808= | Silent (SNP) | VAF 80/168 reads (48%) | catalogued as COSV58797843; called by muse, mutect2, varscan2
- GSDME | c.765G>T p.L255= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV61650705; called by muse, mutect2, varscan2
- HTR3E | c.738G>A p.R246= (on ENST00000415389 / NM_001256613.1; = p.R261= on NM_182589.2) | Silent (SNP) | VAF 113/401 reads (28%) | catalogued as rs770545579, COSV58945705; called by muse, mutect2, varscan2
- IGHV4-59 | c.168C>A p.I56= | Silent (SNP) | VAF 86/267 reads (32%) | catalogued as rs782541919; called by muse, mutect2, varscan2
- IGSF10 | c.5640T>C p.D1880= | Silent (SNP) | VAF 23/172 reads (13%) | catalogued as COSV56781102; called by muse, mutect2, varscan2
- IGSF8 | c.1770G>T p.V590= | Silent (SNP) | VAF 140/269 reads (52%) | catalogued as COSV58757281; called by muse, mutect2, varscan2
- INHBA | c.999C>T p.I333= | Silent (SNP) | VAF 116/247 reads (47%) | catalogued as COSV54219122; called by muse, mutect2, varscan2
- IPO9 | c.2169G>A p.V723= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV64232661; called by muse, mutect2, varscan2
- KRBA2 | c.156T>C p.Y52= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as COSV58778578; called by muse, mutect2, varscan2
- LAMA3 | c.8169C>T p.I2723= (on ENST00000313654 / NM_198129.4; = p.I1114= on NM_000227.6) | Silent (SNP) | VAF 58/725 reads (8%) | catalogued as COSV52528937; called by muse, mutect2
- LPP | c.1509G>C p.V503= | Silent (SNP) | VAF 134/824 reads (16%) | catalogued as rs373435708; called by muse, mutect2, varscan2
- LRRTM4 | c.1743G>A p.P581= | Silent (SNP) | VAF 219/397 reads (55%) | catalogued as rs754954750, COSV69148953; called by muse, mutect2, varscan2
- LY86 | c.432G>A p.L144= | Silent (SNP) | VAF 90/223 reads (40%) | catalogued as COSV57910611; called by muse, mutect2, varscan2
- MC2R | c.699C>A p.A233= | Silent (SNP) | VAF 23/36 reads (64%) | catalogued as COSV59616826, COSV59620245; called by muse, mutect2, varscan2
- MMRN2 | c.2307C>T p.D769= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV64400310; called by muse, mutect2, varscan2
- MUC16 | c.41391C>T p.F13797= | Silent (SNP) | VAF 208/1436 reads (14%) | catalogued as rs1425597879, COSV66689377; called by muse, mutect2, varscan2
- MUTYH | c.858G>T p.V286= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs749815703, COSV58343393; called by muse, mutect2, varscan2
- NPHS1 | c.1368G>T p.R456= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as rs141962470, COSV62286092; called by muse, mutect2, varscan2
- NRG3 | c.930G>A p.L310= | Silent (SNP) | VAF 53/277 reads (19%) | catalogued as COSV64541388; called by muse, mutect2, varscan2
- NUDT17 | c.642G>A p.L214= | Silent (SNP) | VAF 119/209 reads (57%) | catalogued as COSV57906483; called by muse, mutect2, varscan2
- OGFOD2 | c.441G>T p.A147= (on ENST00000228922 / NM_001304833.1; = p.A87= on NM_024623.3) | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs375496902, COSV57440476; called by muse, mutect2, varscan2
- OR2F2 | c.366C>A p.R122= | Silent (SNP) | VAF 163/405 reads (40%) | catalogued as COSV68832452; called by muse, mutect2, varscan2
- OR5B2 | c.495T>G p.S165= | Silent (SNP) | VAF 47/326 reads (14%) | catalogued as COSV56907341; called by muse, mutect2, varscan2
- P3H1 | c.870A>T p.P290= | Silent (SNP) | VAF 81/156 reads (52%) | catalogued as COSV52531305, COSV52536943; called by muse, mutect2, varscan2
- PAPPA2 | c.1728C>A p.T576= | Silent (SNP) | VAF 125/395 reads (32%) | catalogued as COSV62772025; called by muse, mutect2, varscan2
- PATL1 | c.2043G>A p.Q681= | Silent (SNP) | VAF 182/712 reads (26%) | catalogued as COSV55687594; called by muse, mutect2, varscan2
- PCDHB5 | c.1569G>A p.L523= | Silent (SNP) | VAF 65/90 reads (72%) | catalogued as COSV50647134; called by muse, mutect2, varscan2
- PCNT | c.8904C>G p.L2968= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV64024536; called by muse, mutect2, varscan2
- PHF10 | c.1383T>C p.F461= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV59320820; called by muse, mutect2, varscan2
- PIKFYVE | c.1341G>A p.T447= | Silent (SNP) | VAF 77/250 reads (31%) | catalogued as rs762093065, COSV52236258; called by muse, mutect2, varscan2
- PLG | c.342G>T p.T114= | Silent (SNP) | VAF 104/208 reads (50%) | catalogued as rs776970597, COSV51980374; called by muse, mutect2
- PPFIBP2 | c.2319C>T p.L773= | Silent (SNP) | VAF 60/121 reads (50%) | catalogued as COSV55073892; called by muse, mutect2, varscan2
- PSME4 | c.639T>C p.Y213= | Silent (SNP) | VAF 65/112 reads (58%) | catalogued as rs193125032, COSV66362911; called by muse, mutect2, varscan2
- PTDSS2 | c.1311A>G p.T437= | Silent (SNP) | VAF 17/23 reads (74%) | catalogued as COSV57276816; called by muse, mutect2, varscan2
- RANBP2 | c.201T>C p.G67= | Silent (SNP) | VAF 111/566 reads (20%) | catalogued as COSV51695479; called by muse, mutect2, varscan2
- RBL2 | c.3208C>A p.R1070= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as COSV50872691; called by muse, mutect2, varscan2
- RNF146 | c.378A>G p.E126= (on ENST00000368314 / NM_001242850.2; = p.E125= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 62/252 reads (25%) | catalogued as COSV58931128; called by muse, mutect2, varscan2
- SLC12A1 | c.2013C>A p.T671= | Silent (SNP) | VAF 45/58 reads (78%) | catalogued as COSV66791245; called by muse, mutect2, varscan2
- SLC16A7 | c.1086C>T p.L362= | Silent (SNP) | VAF 68/318 reads (21%) | catalogued as COSV53891526; called by muse, mutect2, varscan2
- SLC17A4 | c.702C>A p.I234= | Silent (SNP) | VAF 304/714 reads (43%) | catalogued as COSV64955447; called by muse, mutect2, varscan2
- SLC22A11 | c.405G>A p.V135= | Silent (SNP) | VAF 45/132 reads (34%) | catalogued as rs753662894, COSV57251534; called by muse, mutect2, varscan2
- SLC44A5 | c.787C>T p.L263= | Silent (SNP) | VAF 57/225 reads (25%) | catalogued as COSV63757811; called by muse, mutect2, varscan2
- SLC7A9 | c.129C>T p.I43= | Silent (SNP) | VAF 106/942 reads (11%) | catalogued as COSV50082754; called by muse, mutect2, varscan2
- SPAG16 | c.624A>G p.K208= | Silent (SNP) | VAF 50/72 reads (69%) | catalogued as COSV55982920; called by muse, mutect2, varscan2
- SRCIN1 | c.2706G>T p.P902= (on ENST00000621492; = p.P868= on NM_025248.3) | Silent (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- STAC | c.1185C>A p.P395= | Silent (SNP) | VAF 172/219 reads (79%) | catalogued as COSV56206020; called by muse, mutect2, varscan2
- SURF4 | c.66G>A p.K22= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV64338645; called by muse, mutect2
- SYTL5 | c.1371G>A p.R457= | Silent (SNP) | VAF 22/31 reads (71%) | catalogued as rs1443438516, COSV52897955; called by muse, mutect2
- TCN1 | c.180C>A p.S60= | Silent (SNP) | VAF 267/627 reads (43%) | catalogued as COSV57251854; called by muse, mutect2, varscan2
- TENM1 | c.7773T>C p.T2591= | Silent (SNP) | VAF 135/184 reads (73%) | catalogued as COSV64424018; called by muse, mutect2, varscan2
- TEX15 | c.1647G>A p.V549= (on ENST00000256246; = p.V932= on NM_001350162.2) | Silent (SNP) | VAF 65/86 reads (76%) | catalogued as rs760084341, COSV56340950; called by muse, mutect2, varscan2
- THSD7B | c.1077A>G p.P359= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV55648507; called by muse, mutect2, varscan2
- TRPV5 | c.2076G>A p.A692= | Silent (SNP) | VAF 129/281 reads (46%) | catalogued as rs777364369, COSV54682716; called by muse, mutect2, varscan2
- TTN | c.67779T>A p.I22593= (on ENST00000591111; = p.I15169= on NM_003319.4) | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV59861650; called by muse, mutect2, varscan2
- TUBB8 | c.1197G>T p.T399= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV100225994; called by muse, mutect2, varscan2
- UBE2E3 | c.591A>T p.I197= | Silent (SNP) | VAF 78/184 reads (42%) | catalogued as COSV66583707, COSV66586104; called by muse, mutect2, varscan2
- UNC13A | c.4467G>A p.P1489= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as rs754427518, COSV53187002; called by muse, mutect2, varscan2
- USP34 | c.8706G>T p.L2902= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as COSV68397392, COSV68401750; called by muse, mutect2, varscan2
- ZBED9 | c.1410G>A p.Q470= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as COSV71729128; called by muse, mutect2, varscan2
- ZFAT | c.162A>T p.T54= | Silent (SNP) | VAF 96/162 reads (59%) | catalogued as COSV64733743, COSV64738025; called by muse, mutect2
- ZIC4 | c.507C>A p.A169= | Silent (SNP) | VAF 254/511 reads (50%) | catalogued as COSV67170468, COSV67172242; called by muse, mutect2, varscan2
- ZNF195 | c.135C>T p.L45= | Silent (SNP) | VAF 85/428 reads (20%) | catalogued as COSV50001613; called by muse, mutect2, varscan2
- ZNF608 | c.2682C>T p.P894= | Silent (SNP) | VAF 105/123 reads (85%) | catalogued as COSV100101475, COSV60434832; called by muse, mutect2, varscan2
- ZNF85 | c.297G>A p.V99= | Silent (SNP) | VAF 29/142 reads (20%) | catalogued as rs754912998, COSV56020892; called by muse, mutect2, varscan2
- GALNT10 | c.568+17481G>A | Intron (SNP) | VAF 26/104 reads (25%) | catalogued as COSV51719815; called by muse, mutect2, varscan2
- LCOR | chr10:96828741 T>C | 5'Flank (SNP) | VAF 7/8 reads (88%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71641020 C>G | 3'Flank (SNP) | VAF 49/153 reads (32%) | catalogued as COSV51703885; called by muse, mutect2, varscan2
- MGA | c.1065-4431C>G | Intron (SNP) | VAF 36/114 reads (32%) | catalogued as COSV54947689; called by muse, mutect2, varscan2
- SMARCB1 | c.363-2268C>A | Intron (SNP) | VAF 40/174 reads (23%) | catalogued as COSV54092816; called by muse, mutect2, varscan2
- SSPOP | n.15090C>A | RNA (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
